Surgical pathology report (de-identified scan), TCGA case TCGA-99-7458, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Alabama, specimen TCGA-99-7458-01A (Primary Tumor).

[page 1 of 5]
Patient Name

MR#

Observation Date

Last Edited Date

SURGICAL PATHOLOGY

Diagnosis

Lymph node, #9, resection:

- Negative for malignancy.

Lung, superior segment, right lower lobe:

- Well differentiated adenocarcinoma with bronchioloalveolar features (1.2 cm in maximum dimension).
- Leiomyoma (0.2 cm).
- Shaved surgical margin is positive for bronchioloalveolar carcinoma.

Lymph node, #8, excision: - Single lymph node with no evidence of malignancy (0/1).

Lymph node, #7, excision: - Single lymph node with no evidence of malignancy (0/1).

Lymph node, #4R, excision:- Multiple fragments of lymph node with no evidence of malignancy.

Lymph node, #2R, excision:- Multiple fragments of lymph node with no evidence of malignancy.

Right upper lobe, posterior segment, wedge resection:- Bronchioalveolar carcinoma (0.9 cm as measured microscopically on slide G3), please see comment. - Carcinoid tumorlet (0.4 cm). - Focal granulomatous inflammation. - Shaved surgical margin shows a microscopic focus of bronchioloalveolar carcinoma.

Lung, right lower lobe, wedge: - Bronchioloalveolar carcinoma (0.7 cm), present at cauterized margins.

- Focal granulomatous inflammation.

Lung, anterior basilar right lower lobe, wedge resection: - Well differentiated adenocarcinoma with bronchioloalveolar features (1.6 cm).- Multiple carcinoid tumorlets (0.2 cm, 0.2 cm, and 0.1 cm) as measured microscopically on slide I4. - Leiomyoma (0.2 cm as measured microscopically on slide I4).

- Focal granulomatous inflammation.
- Surgical resection margins appear negative for malignancy.

Lymph node, #10, excision: - Single lymph node with no evidence of malignancy (0/1).

Pathologist Comments: The multifocality of this tumor give it a stage pT3 pN0 pMx. Invasive well differentiated adenocarcinoma with bronchioloalveolar features is present in the superior segment of the right lower lobe and the anterior basilar right lower lobe. Additionally, bronchioloalveolar carcinoma is identified and the posterior segment of the right upper lobe and an undesignated site of the right lower lobe. The superior segment of the right upper lobe was previously called negative for malignancy at the time of frozen section. No nodule was identified upon gross examination of the specimen. A representative section was taken and submitted for frozen section. Upon review, the frozen section slides show no evidence of malignancy. In addition to the malignant tumor, multiple carcinoid tumorlets and leiomyomas are identified in separate specimens.

Clinical Information:

Frozen Section Diagnosis

AFS1: Lymph node, #9, resection:

- Negative for malignancy.
- Hyalinized granuloma.

BFS1: Lung, superior segment, right lower lobe:

- Non small cell carcinoma, favor adenocarcinoma.

GFS1: Lung, posterior segment, right upper lobe, resection:

- Negative for malignancy.

[page 2 of 5]
- Fibrous pleural thickening/pathologic lung tissue present.

HFS1: Lung, right lower lobe, resection:

- Non small cell carcinoma.

All frozen section evaluation were

Gross Description

Part A is received fresh for frozen section labeled with the patient's name, medical record number and designated "#9 lymph node." The specimen consists of a multiple fragments of tan soft tissue measuring 0.3 x 0.5 x 0.4 cm in aggregate. The specimen was submitted in its entirety for frozen section and is now resubmitted in its entirety for permanent section. Part B is received fresh for frozen section in a container further designated "#2 - superior segment right right lower lobe." The specimen consists of a 9 x 5.4 x 2.5 cm segment of lung with a 1.2 x 0.8 x 0.7 cm firm tan nodule. Representative section of tumor was taken for frozen section and is now resubmitted for permanent in cassette B1. The nodule is located 2 cm away from the nearest stapled surgical resection margin. The stapled surgical resection margin in this area is shaved and submitted in cassette B2. Additional representative sections of the nodule are taken and submitted in cassette B3. The rest of the specimen is serially sectioned to reveal unremarkable spongy, tan-brown lung parenchyma. A 0.2 cm nodule is identified and submitted and submitted in cassette B4. No other lesions are identified. Part C is received in a container labeled with the patient's name, medical record number and designated "lymph node #8." The specimen consists of a single fragment of blackened soft tissue which measures 0.5 x 0.3 x 0.2 cm. The specimen is submitted in its entirety. Part D is received in a container labeled with the patient's name, medical record number and designated "lymph node #7." The specimen consists of a single fragment of blackened soft tissue measuring 1.8 x 1.3 x 1.2 cm. The specimen is submitted in its entirety. Part E is received in a container labeled with the patient's name, medical record number and designated "lymph node #4R." The specimen consists of a multiple fragments of yellow and tan soft tissue measuring 2.5 x 2.0 x 1.1 cm. The palpation reveals two probable lymph nodes which are submitted in their entirety unbisected. Multiple smaller lymph nodes are embedded in the accompanying soft tissue. These are submitted in their entirety unbisected. Part F is received in a container labeled with the patient's name, medical record number and designated "lymph node #2R." The specimen consists of a multiple fragments of yellow soft tissue which measures 2.1 x 1.4 x 1.1 cm. The specimen is submitted in its entirety. Part G is received in a container further designated "posterior segment, right upper lobe." The specimen consists of a 12 x 4.5 x 2.7 cm segment of lung. The specimen was serially sectioned to reveal a focal area of fibrous thickening and is approximately 2.5 x 1.0 x 0.2 cm. Representative sections were submitted for frozen section and now resubmitted for permanent in cassette G1. The specimen is further serially sectioned to reveal tan-brown spongy lung parenchyma with no other lesions identified. Representative sections are taken and submitted in cassette G2 and G3. Part H is received fresh for frozen section labeled with the patient's name, medical record number and designated "lung, right lower lobe." The specimen consists of a fragment of tan soft tissue measuring 1.9 x 1.5 x 0.6 cm. Sectioning of the specimen reveals a tan nodule which is 0.7 cm in its greatest dimension. This nodule was submitted in its entirety for frozen section and is now resubmitted in its entirety. The remainder of the specimen is also submitted in its entirety. Part I is received in a container labeled with the patient's name, medical record number and designated "anterior basilar right lower lobe." The specimen consists of a fragment of red to pink pulmonary tissue measuring 7.5 x 5.0 x 1.4 cm. There is a stapled margin present. The area adjacent to the stapled margin is inked black and the staples are removed. The tissue adjacent to the staple is submitted in its entirety in cassette I1 and I2. The specimen is serially sectioned revealing a tan nodule within the lung parenchyma which measures 1.6 x 1.2 x 1.2 cm. This lesion lies 0.9 cm from the now shaved stapled margin. Representative sections are submitted. Part J is received in a container labeled with the patient's name, medical record number and designated "level 10 lymph node." The specimen consists of single fragment of blackened tan soft tissue measuring 0.7 x 0.3 x 0.4 cm. The specimen is submitted in its entirety.

Block Summary

- A1- Level 9 lymph node.
- B1- Superior segment, right lower lobe, tumor, frozen section.
- B2- Superior segment, right lower lobe, stapled surgical margin closest to tumor, shaved.
- B3- Tumor.
- B4- Separate 0.2 cm nodule.
- C1- Lymph node #8.
- D1- Lymph node #7.
- E1- Two lymphs unbisected.
- E2- Multiple small lymph nodes unbisected.
- F1- Lymph node #2R.
- G1- Posterior segment, right upper lobe, frozen section.
- G2-G3 Posterior segment, right upper lobe.
- H1- Remainder of frozen section.
- H2- Remainder of right lower lobe wedge.
- I1-I2 Inked stapled margin.

[page 3 of 5]
- 13- Full section showing the lesion.
- 14- Two representative sections of normal appearing lung.
- 15- Representative sections showing nodule adjacent to normal lung.
- J1- Lymph node #10.

Microscopic Description

A microscopic examination has been performed. ■

SP Synoptic Report

B: Thorax Lung

SPECIMEN: Lobe(s) of lung: Superior segment right lower lobe

PROCEDURE: Wedge resection

SPECIMEN INTEGRITY: Intact

SPECIMEN LATERALITY: Right

TUMOR SITE: Lower lobe

TUMOR SIZE: Greatest dimension: 1.2 cm

TUMOR FOCALITY: Separate tumor nodules in same lobe

HISTOLOGIC TYPE: Adenocarcinoma

HISTOLOGIC GRADE: G1: Well differentiated

VISCERAL PLEURA INVASION: Not identified

TUMOR EXTENSION: Not identified

BRONCHIAL MARGIN: Not applicable

VASCULAR MARGIN: Not applicable

PARENCHYMAL MARGIN: Uninvolved by invasive carcinoma

PARIETAL PLEURAL MARGIN: Uninvolved by invasive carcinoma

CHEST WALL MARGIN: Not applicable

OTHER ATTACHED TISSUE MARGIN: Not applicable

TREATMENT EFFECT: Not applicable

LYMPH-VASCULAR INVASION: Not identified

LYMPH NODES: Not identified

TNM DESCRIPTORS: m (multiple primary tumors)

PRIMARY TUMOR (pT): pT3: Tumor > 7 cm in greatest dimension; or Tumor of any size that directly invades any of the following: chest wall (including superior sulcus tumors), diaphragm, phrenic nerve, mediastinal pleura, parietal pericardium; or Tumor in the main bronchus < 2 cm distal to the carina but w/o involvement of the carina; or Tumor with atelectasis or obstructive pneumonitis of the entire lung; or Tumors with separate tumor nodule(s) in same lobe

REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis

DISTANT METASTASIS (pM): Not applicable

COMMENT(S): Bronchioloalveolar carcinoma present at surgical resection margin (no invasive component at margin).

G: Thorax Lung

SPECIMEN: Lobe(s) of lung: Superior segment right upper lobe

PROCEDURE: Wedge resection

SPECIMEN INTEGRITY: Intact

SPECIMEN LATERALITY: Right

TUMOR SITE: Upper lobe

TUMOR SIZE: Greatest dimension: 0.9 cm

TUMOR FOCALITY:

Separate tumor nodules in different lobes: Superior segment right lower lobe, anterior basilar right lower lobe

HISTOLOGIC TYPE: Bronchioloalveolar carcinoma

HISTOLOGIC GRADE: G1: Well differentiated

VISCERAL PLEURA INVASION: Not identified

TUMOR EXTENSION: Not identified

BRONCHIAL MARGIN: Cannot be assessed

VASCULAR MARGIN: Cannot be assessed

PARENCHYMAL MARGIN: Uninvolved by invasive carcinoma

PARIETAL PLEURAL MARGIN: Uninvolved by invasive carcinoma

CHEST WALL MARGIN: Cannot be assessed

OTHER ATTACHED TISSUE MARGIN: Not applicable

TREATMENT EFFECT: Not applicable

LYMPH-VASCULAR INVASION: Not identified

[page 4 of 5]
LYMPH NODES: Not identified
TNM DESCRIPTORS: m (multiple primary tumors)
PRIMARY TUMOR (pT): pT3: Tumor > 7 cm in greatest dimension; or Tumor of any size that directly invades any of the following: chest wall (including superior sulcus tumors), diaphragm, phrenic nerve, mediastinal pleura, parietal pericardium; or Tumor in the main bronchus < 2 cm distal to the carina but w/o involvement of the carina; or Tumor with atelectasis or obstructive pneumonitis of the entire lung; or Tumors with separate tumor nodule(s) in same lobe

REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis
DISTANT METASTASIS (pM): Not applicable
COMMENT(S): Bronchioloalveolar carcinoma is microscopically present at the surgical resection margin.

H: Thorax Lung
SPECIMEN:
Lobe(s) of lung: Right lower lobe
PROCEDURE: Wedge resection
SPECIMEN INTEGRITY: Intact

SPECIMEN LATERALITY: Right
TUMOR SITE: Lower lobe
TUMOR SIZE: Greatest dimension: 0.7 cm
TUMOR FOCALITY: Separate tumor nodules in different lobes: Superior segment right lower lobe, anterior basilar right lower lobe

HISTOLOGIC TYPE: Bronchioloalveolar carcinoma
HISTOLOGIC GRADE: G1: Well differentiated
VISCERAL PLEURA INVASION: Not identified
TUMOR EXTENSION: Not identified
BRONCHIAL MARGIN: Not applicable
VASCULAR MARGIN: Not applicable
PARENCHYMAL MARGIN: Uninvolved by invasive carcinoma
PARIETAL PLEURAL MARGIN: Uninvolved by invasive carcinoma
CHEST WALL MARGIN: Cannot be assessed
OTHER ATTACHED TISSUE MARGIN: Not applicable
TREATMENT EFFECT: Not applicable
LYMPH-VASCULAR INVASION: Not identified
LYMPH NODES: Not identified

TNM DESCRIPTORS: m (multiple primary tumors)
PRIMARY TUMOR (pT): pT3: Tumor > 7 cm in greatest dimension; or Tumor of any size that directly invades any of the following: chest wall (including superior sulcus tumors), diaphragm, phrenic nerve, mediastinal pleura, parietal pericardium; or Tumor in the main bronchus < 2 cm distal to the carina but w/o involvement of the carina; or Tumor with atelectasis or obstructive pneumonitis of the entire lung; or Tumors with separate tumor nodule(s) in same lobe

REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis
DISTANT METASTASIS (pM): Not applicable
COMMENT(S): Bronchioloalveolar carcinoma is present at cauterized surgical margin.

I: Thorax Lung
SPECIMEN: Lobe(s) of lung: Anterior basilar right lower lobe
PROCEDURE: Wedge resection
SPECIMEN INTEGRITY: Intact
SPECIMEN LATERALITY: Right
TUMOR SITE: Lower lobe
TUMOR SIZE: Greatest dimension: 1.6 cm
TUMOR FOCALITY: Separate tumor nodules in different lobes: Superior segment right lower lobe, right lower lobe

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G1: Well differentiated
VISCERAL PLEURA INVASION: Not identified
TUMOR EXTENSION: Not identified
BRONCHIAL MARGIN: Not applicable
VASCULAR MARGIN: Not applicable

[page 5 of 5]
PARENCHYMAL MARGIN: Uninvolved by invasive carcinoma
PARIETAL PLEURAL MARGIN: Uninvolved by invasive carcinoma
CHEST WALL MARGIN: Not applicable
OTHER ATTACHED TISSUE MARGIN: Not applicable
TREATMENT EFFECT: Not applicable
LYMPH-VASCULAR INVASION: Not identified
LYMPH NODES: Not identified
TNM DESCRIPTORS: m (multiple primary tumors)

PRIMARY TUMOR (pT): pT3: Tumor > 7 cm in greatest dimension; or Tumor of any size that directly invades any of the following: chest wall (including superior sulcus tumors), diaphragm, phrenic nerve, mediastinal pleura, parietal pericardium; or Tumor in the main bronchus < 2 cm distal to the carina but w/o involvement of the carina; or Tumor with atelectasis or obstructive pneumonitis of the entire lung; or Tumors with separate tumor nodule(s) in same lobe
REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis

Immunohistochemical stains show that the carcinoid tumorlet is reactive with chromogranin and synaptophysin with satisfactory controls. The diagnosis remains unchanged.

Source: NCI Genomic Data Commons file f0512b96-344c-479b-84ae-8944b1df63e7 (TCGA-99-7458.D17D08C5-429B-413F-8ED6-984BC2021392.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).